Gene-level copy-number profile of tumor specimen TCGA-AP-A052-01A from TCGA case TCGA-AP-A052, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 59.5 years (21,721 days).
Specimen TCGA-AP-A052-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.52e7aae5-51fd-441c-a0d4-edea3cc46ec2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AP-A052-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 830 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/27d644d3-c01a-49aa-8fc6-0df6bdfa2831

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 10,882; copy number 2: 45,195; copy number 3: 3,268; copy number 4: 217; copy number 5: 194.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AP-A052-01A-11D-A00X-01): tumor purity 0.89, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:8,980,591–9,363,053, 4 genes (within-gene range 0–1): SRGAP3, SRGAP3-AS1, AC037193.1, SRGAP3-AS2.
- chr10:87,500,337–88,049,823, 17 genes: AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.
- chr16:25,031,744–25,185,538, 10 genes: AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P.
- chr16:73,794,057–73,941,781, 3 genes: AC087565.2, AC087565.1, AC092128.1.
- chr16:74,053,365–74,053,965, 1 gene: AC138627.2.
- chr18:69,831,158–69,961,803, 1 gene: CD226.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 194 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:34,733,298–38,229,714, 193 genes, copy number 5 (broad region; genes not listed).
- chr19:38,251,237–38,256,532, 1 gene, copy number 5: PPP1R14A.

Autosomal genes at a single copy (total copy number 1): 10,880. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
